Somatic mutation profile of tumor specimen TCGA-IG-A4QS-01A (aliquot TCGA-IG-A4QS-01A-11D-A27G-09) from TCGA case TCGA-IG-A4QS, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Thoracic esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.9 years (26,273 days).
Specimen TCGA-IG-A4QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0843944c-d92f-49c3-bb6f-b57395d53751.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A4QS-10A (Blood Derived Normal), aliquot TCGA-IG-A4QS-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/488b5ae6-0bc7-48aa-95b8-b4c6bcd1d986

The open-access MAF lists 238 somatic variants for this specimen: 191 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 44, Nonsense Mutation 9, Frame Shift Del 7, Splice Region 3, Frame Shift Ins 2, In Frame Del 2, 5'UTR 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPHS2 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs74315347, CM000584; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 300/400 reads (75%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.5571C>T p.S1857= | Splice Region (SNP) | VAF 26/32 reads (81%) | catalogued as rs764814616, COSV54023450; called by muse, mutect2, varscan2
- ADAMTS12 | c.2449C>A p.L817I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as COSV100710462; called by muse, mutect2, varscan2
- ADAMTS19 | c.3224A>C p.K1075T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1278081498, COSV50745195; called by muse, mutect2, varscan2
- ADAMTS2 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs375191740; called by muse, mutect2, varscan2
- APOB | c.6519A>C p.Q2173H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51923181; called by muse, mutect2, varscan2
- BNC1 | c.225dup p.M76Hfs*17 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs751941533; called by mutect2, varscan2
- BRINP3 | c.286T>C p.F96L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.303); catalogued as COSV66529546; called by muse, mutect2, varscan2
- C1GALT1C1L | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as rs1340321132; called by muse, mutect2
- CCDC54 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1323402029; called by muse, mutect2, varscan2
- CEP350 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs745667197, COSV62485752; called by muse, mutect2, varscan2
- CHD4 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV58898475; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- COL9A2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs767929481; called by muse, mutect2, varscan2
- CSMD3 | c.7694T>A p.I2565K (on ENST00000297405 / NM_001363185.1; = p.I2461K on NM_052900.3) | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.709); catalogued as COSV52126796; called by muse, mutect2
- DMD | c.5221T>G p.L1741V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63747107, COSV63789783; called by muse, mutect2, varscan2
- DNAJC3 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.167); catalogued as rs767370853, COSV65132316; called by muse, mutect2, varscan2
- DPYS | c.1171A>G p.R391G | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV59826759, COSV59826868, COSV59826998; called by muse, mutect2
- DSCAML1 | c.2102C>T p.S701L (on ENST00000321322; = p.S641L on NM_020693.4) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.207); catalogued as rs915240729; called by muse, varscan2
- EFCAB1 | c.72A>C p.E24D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50618028; called by muse, mutect2, varscan2
- EIF3A | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1363194440, COSV64963624; called by muse, mutect2, varscan2
- EPHA5 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV99896989; called by muse, mutect2, varscan2
- EXT1 | c.1642del p.S548Afs*73 | Frame Shift Del (DEL) | VAF 48/62 reads (77%) | catalogued as CD012248; called by mutect2, varscan2
- FAM71C | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60944727; called by muse, mutect2, varscan2
- FHL5 | c.814T>G p.F272V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100459374; called by muse, mutect2, varscan2
- GPRASP2 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100176929; called by muse, mutect2, varscan2
- GRK6 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs200876617, COSV100586879; called by muse, mutect2, varscan2
- GUCY1A2 | c.1439del p.H480Pfs*23 | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | catalogued as COSV56505998; called by mutect2, pindel, varscan2
- HCK | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1365132925; called by muse, mutect2, varscan2
- HCN1 | c.676T>C p.F226L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV100302599; called by muse, mutect2, varscan2
- HDAC9 | c.2171A>C p.K724T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV101287888; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs747516113; called by muse, mutect2, varscan2
- INHBA | c.523del p.L175Sfs*23 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | catalogued as COSV54223510; called by mutect2, pindel, varscan2
- IVL | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as COSV99056482; called by muse, mutect2, varscan2
- KCNA1 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779656199, COSV66836979; called by muse, mutect2, varscan2
- KCNH2 | c.1947C>T p.S649= | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as rs1423653286; called by muse, mutect2, varscan2
- KIAA1755 | c.295T>G p.L99V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV54080496, COSV54080663; called by muse, mutect2, varscan2
- KIF22 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.189); catalogued as rs751925003; called by muse, mutect2, varscan2
- KLRG1 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99868392; called by muse, mutect2, varscan2
- KRT84 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.829); catalogued as rs149169317; called by muse, mutect2, varscan2
- L3MBTL4 | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV53118685; called by muse, mutect2, varscan2
- LILRA4 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749644963, COSV52492535; called by muse, mutect2
- LRIG1 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as rs267599927; called by muse, mutect2, varscan2
- LRRC4C | c.1739C>G p.P580R | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.031); catalogued as COSV53420384, COSV53427977, COSV53435420; called by muse, mutect2, varscan2
- LRRC4C | c.1421A>C p.N474T | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53431955; called by muse, mutect2, varscan2
- LZTR1 | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs377075596; called by muse, mutect2, varscan2
- MGAT1 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | PolyPhen benign (0.191); catalogued as rs759196211, COSV100286874; called by muse, mutect2
- MINAR1 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs542789268, COSV59582821; called by muse, mutect2, varscan2
- MSR1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs569058358, COSV100026916, COSV50516677; called by muse, mutect2, varscan2
- MTUS2 | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1032162429, COSV54993235; called by muse, mutect2, varscan2
- MYH2 | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs148326504, COSV99063296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDUFB9 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs199940282, COSV52675393; called by muse, mutect2, varscan2
- NLRP13 | c.2468C>T p.S823L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs367708599, COSV61621787; called by muse, mutect2
- NRK | c.2342A>C p.K781T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1242082458; called by muse, mutect2, varscan2
- OR2T10 | c.136A>C p.I46L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1384432086; called by muse, mutect2, varscan2
- OR5D14 | c.482T>A p.L161H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs1200762670; called by muse, mutect2
- OR6K2 | c.430A>C p.T144P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs1192392948; called by muse, mutect2
- OTOP2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200725611, COSV58881356; called by muse, mutect2, varscan2
- PLCE1 | c.5409G>A p.M1803I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs755528503; called by muse, mutect2, varscan2
- PROS1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as rs1455675811, CD041929, CM041821, CM951049; called by muse, mutect2, varscan2
- QRICH2 | c.4606C>T p.P1536S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as rs1369380611; called by muse, mutect2, varscan2
- RIN1 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs753504307, COSV100255004; called by muse, varscan2
- RTL3 | c.767T>G p.V256G | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV58183628; called by muse, mutect2, varscan2
- RXYLT1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.172); catalogued as COSV99707082; called by muse, mutect2, varscan2
- RYR2 | c.13130C>T p.S4377L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as rs869025514, COSV100772641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCARF1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs200018599; called by muse, mutect2, varscan2
- SCN9A | c.2432T>G p.F811C (on ENST00000303354; = p.F800C on NM_002977.3) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100314447, COSV57599792; called by muse, mutect2, varscan2
- SLC38A10 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750418123, COSV55842228; called by muse, mutect2, varscan2
- SLC5A10 | c.1384G>A p.V462I (on ENST00000395645 / NM_001042450.4; = p.V478I on NM_152351.5) | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs769478843, COSV99408237; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2209G>A p.D737N (on ENST00000540229 / NM_001371097.1; = p.D676N on NM_001009562.4) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs951327157, COSV67446610; called by muse, mutect2, varscan2
- SLITRK5 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as rs1280990449, COSV61524571; called by muse, mutect2, varscan2
- SNCAIP | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1175100479, COSV54421080; called by muse, mutect2, varscan2
- SPAG16 | c.1687A>C p.S563R | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.941); catalogued as rs1278165214, COSV100530109, COSV100536780; called by muse, mutect2, varscan2
- SPTLC3 | c.1114A>G p.S372G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100982890, COSV65464481; called by muse, mutect2, varscan2
- STPG1 | c.823G>A p.V275M (on ENST00000337248 / NM_001199013.2; = p.V228M on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528552913; called by muse, mutect2, varscan2
- TAS2R16 | c.557T>G p.V186G | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV50797167; called by muse, mutect2, varscan2
- TECTA | c.1813G>A p.V605M | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1390890390, COSV50691392, COSV50708999; called by muse, mutect2, varscan2
- TENM1 | c.5801G>A p.R1934Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64441616; called by muse, mutect2, varscan2
- THBS1 | c.3022T>G p.F1008V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52952684; called by muse, mutect2, varscan2
- THEMIS | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64071372; called by muse, mutect2, varscan2
- TMPRSS5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs371934092; called by muse, varscan2
- U2SURP | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1210716236; called by muse, mutect2
- VPS35 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs779434158; called by muse, mutect2, varscan2
- VWA7 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866775083; called by muse, mutect2, varscan2
- WDR17 | c.1127T>G p.L376R | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs778121595; called by muse, mutect2, varscan2
- XRCC6 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.053); catalogued as rs61754572; called by muse, mutect2, varscan2
- ZFHX4 | c.3209A>C p.K1070T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.674); catalogued as COSV50816032, COSV51501017; called by muse, mutect2, varscan2
- ZNF112 | c.1873C>T p.Q625* (on ENST00000337401 / NM_001083335.2; = p.Q619* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 29/112 reads (26%) | catalogued as COSV61619387; called by muse, mutect2, varscan2
- ZNF512B | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs761628206, COSV53871321; called by muse, mutect2, varscan2
- ZNF561 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs779531767; called by muse, mutect2, varscan2
- ZNF585B | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100459484; called by muse, mutect2, varscan2
- ZNF648 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV60569574; called by muse, mutect2, varscan2
- ABCA12 | c.1184del p.N395Ifs*2 (on ENST00000272895 / NM_173076.3; = p.N77Ifs*2 on NM_015657.3) | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- ABCA6 | c.2876A>G p.D959G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ACSBG1 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ADRA1D | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGTR2 | c.354A>C p.K118N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKK1 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARAP2 | c.3593_3595del p.D1198del | In Frame Del (DEL) | VAF 8/41 reads (20%) | called by pindel, varscan2
- ASB7 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2
- BCL9L | c.2281G>T p.V761L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- CACNA1D | c.4233C>G p.I1411M (on ENST00000350061 / NM_001128840.3; = p.I1431M on NM_000720.4) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH19 | c.1840T>G p.L614V | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CHODL | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLSTN2 | c.2531T>C p.L844P | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTN1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2
- CSMD1 | c.6696A>C p.Q2232H (on ENST00000520002; = p.Q2231H on NM_033225.6) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSMD2 | c.7960C>T p.R2654* | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- CSMD3 | c.9665G>C p.S3222T (on ENST00000297405 / NM_001363185.1; = p.S3053T on NM_052900.3) | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); called by muse, mutect2
- CYP7B1 | c.963A>C p.E321D | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCN | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DNAH2 | c.902A>T p.K301M | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- DNAH7 | c.2174T>G p.L725R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EARS2 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ELP2 | c.2088G>A p.W696* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- FAM102B | c.267del p.G90Vfs*13 | Frame Shift Del (DEL) | VAF 28/108 reads (26%) | called by mutect2, pindel, varscan2
- GNAS | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- GOLGB1 | c.9598C>T p.Q3200* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- GRM1 | c.82T>A p.L28M | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM7 | c.554A>G p.E185G | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HMBS | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA4L | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- IGKV3D-11 | c.303A>C p.E101D | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- KIAA1109 | c.12362G>T p.G4121V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KIAA1210 | c.3928G>C p.V1310L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- KIF5B | c.2314C>A p.Q772K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.041); called by muse, varscan2
- LAS1L | c.1254C>A p.Y418* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- LDB2 | c.9C>A p.S3R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LIPI | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- LRRC1 | c.128T>A p.L43Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRTM1 | c.462A>C p.Q154H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.066); called by muse, mutect2
- MACROD2 | c.1273A>G p.S425G (on ENST00000642719; = p.S397G on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.647); called by muse, varscan2
- MAGEA12 | c.368A>C p.K123T | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCO | c.342A>T p.Q114H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MARK1 | c.2216T>G p.L739W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MDC1 | c.3285_3290del p.S1096_E1097del | In Frame Del (DEL) | VAF 18/113 reads (16%) | called by mutect2, pindel, varscan2
- MIER1 | c.409C>T p.Q137* (on ENST00000355356 / NM_001077701.3; = p.Q154* on NM_020948.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- MMS22L | c.3632G>A p.G1211D | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOCS1 | c.873C>A p.A291= | Splice Region (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- MYB | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MYOCD | c.1424T>G p.F475C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYT1L | c.2624dup p.D876Gfs*34 | Frame Shift Ins (INS) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- NETO1 | c.5T>A p.I2N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- NNT | c.2493G>A p.M831I | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOC3L | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR2C2 | c.592C>T p.R198W (on ENST00000393102; = p.R217W on NM_003298.5) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- OR2M3 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2W3 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- OR6F1 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR8K1 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- OSGIN2 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDH17 | c.1625T>G p.F542C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- PCLO | c.6725A>G p.E2242G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2
- PHYHIPL | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCL1 | c.3034A>C p.K1012Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- PLCXD3 | c.785G>T p.S262I | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PLEKHM3 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- POLQ | c.5971G>A p.V1991M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPFIA2 | c.3128A>C p.E1043A | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PSMD1 | c.2180A>C p.K727T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PTPN14 | c.1527A>C p.K509N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PTPRC | c.3737T>G p.I1246S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, varscan2
- QTRT1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RANBP3L | c.146T>G p.F49C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- RIMS2 | c.4346A>C p.K1449T (on ENST00000666250 / NM_001348490.2; = p.K1020T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RPS6KA1 | c.1976A>T p.D659V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- SCN1A | c.4919T>C p.L1640P (on ENST00000303395 / NM_001202435.3; = p.L1629P on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN1A | c.2413T>G p.L805V (on ENST00000303395 / NM_001202435.3; = p.L794V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SCN7A | c.112T>G p.L38V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SEC24B | c.1842del p.F615Lfs*18 | Frame Shift Del (DEL) | VAF 46/129 reads (36%) | called by mutect2, pindel, varscan2
- SLC12A4 | c.1328A>C p.D443A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- SLC5A4 | c.1335A>C p.Q445H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SNX10 | c.73T>G p.F25V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- SPATA13 | c.959G>T p.C320F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPTLC3 | c.490A>C p.N164H | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ST8SIA4 | c.670del p.W224Gfs*20 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- STON2 | c.2455A>C p.S819R (on ENST00000649389 / NM_001366849.2; = p.S762R on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- SYNE1 | c.20950A>C p.S6984R (on ENST00000367255 / NM_182961.4; = p.S6913R on NM_033071.3) | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TBC1D19 | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TLE4 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- TRANK1 | c.3223T>G p.L1075V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.058); called by muse, mutect2
- TSG101 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2N | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- UBE3B | c.979T>A p.L327I | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- USF3 | c.1897C>T p.L633F | Missense Mutation (SNP) | VAF 89/127 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VEPH1 | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- XAGE2 | c.232A>C p.T78P | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- XKR4 | c.80A>G p.H27R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); called by muse, mutect2
- ZNF703 | c.1731T>G p.Y577* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- ZSCAN5A | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA12 | c.2790T>C p.I930= (on ENST00000272895 / NM_173076.3; = p.I612= on NM_015657.3) | Silent (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.2445T>C p.T815= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV56976480, COSV56976826; called by muse, mutect2, varscan2
- CACNA2D1 | c.1749T>C p.S583= (on ENST00000356253 / NM_001366867.1; = p.S564= on NM_000722.4) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs762286086; called by muse, varscan2
- CDH26 | c.2451A>G p.K817= (on ENST00000348616 / NM_177980.4; = p.K150= on NM_021810.6) | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs948717888; called by muse, mutect2
- CDSN | c.780C>T p.H260= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs566049981, COSV52537552; called by muse, mutect2, varscan2
- CHRD | c.2601T>C p.D867= | Silent (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- CNTN3 | c.2394A>G p.A798= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs755583271, COSV99725653; called by muse, mutect2, varscan2
- COL14A1 | c.5253T>A p.G1751= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- DMAC2 | c.498C>T p.L166= | Silent (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- DOCK10 | c.4479G>A p.L1493= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1250596383; called by muse, mutect2, varscan2
- DPP10 | c.549G>A p.A183= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs371677426; called by muse, mutect2, varscan2
- DRGX | c.63G>A p.S21= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1365095800, COSV65136285; called by muse, mutect2
- DSG1 | c.2880C>T p.G960= | Silent (SNP) | VAF 59/74 reads (80%) | catalogued as rs200560952; called by muse, mutect2, varscan2
- FAM174A | c.573A>G p.*191= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100444435; called by muse, mutect2, varscan2
- FAT4 | c.6057A>G p.Q2019= | Silent (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- IGSF10 | c.168G>A p.P56= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs775388305, COSV56782171; called by muse, mutect2, varscan2
- KLHL13 | c.1602A>G p.G534= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs1486398001; called by muse, mutect2, varscan2
- LRP1B | c.9969T>C p.R3323= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- MARCHF4 | c.555C>G p.V185= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs1290232703, COSV99814128; called by muse, varscan2
- MARK1 | c.1722A>G p.E574= | Silent (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- NRXN1 | c.886T>C p.L296= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV58481897; called by muse, mutect2, varscan2
- OGFRL1 | c.1020T>C p.T340= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs778660135, COSV64971630, COSV64972030; called by muse, mutect2, varscan2
- OR2T10 | c.601T>C p.L201= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs775110216; called by muse, mutect2, varscan2
- OR4C11 | c.294A>G p.Q98= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs755442386; called by muse, mutect2, varscan2
- OR4C46 | c.90T>C p.F30= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- OR52H1 | c.885A>G p.G295= (on ENST00000322653; = p.G301= on NM_001005289.1) | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs1418636496; called by muse, mutect2, varscan2
- OR5D14 | c.171T>C p.F57= | Silent (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- PAX1 | c.723G>A p.P241= | Silent (SNP) | VAF 64/140 reads (46%) | catalogued as rs1434161578, COSV68271351; called by muse, mutect2, varscan2
- PCLO | c.2304T>C p.S768= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.1170A>G p.V390= | Silent (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- PRAMEF6 | c.1098A>G p.Q366= | Silent (SNP) | VAF 75/429 reads (17%) | called by mutect2, varscan2
- PTPRM | c.2580T>G p.T860= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs1252733831; called by muse, mutect2, varscan2
- RGMA | c.1158C>T p.G386= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs201262127; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>C p.L448= (on ENST00000666250 / NM_001348490.2; = p.L256= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV51669105, COSV51676746; called by muse, mutect2
- RXRG | c.474C>T p.G158= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as rs1246150145; called by muse, mutect2, varscan2
- SIM1 | c.1221C>T p.G407= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1335620956, COSV99492869; called by muse, mutect2
- SPANXN1 | c.135G>A p.T45= | Silent (SNP) | VAF 66/102 reads (65%) | catalogued as rs1556883074; called by muse, mutect2, varscan2
- SPART | c.441T>C p.T147= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100768605; called by muse, mutect2, varscan2
- TLR4 | c.1176T>C p.S392= (on ENST00000355622 / NM_138554.5; = p.S352= on NM_003266.4) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV62923468; called by muse, mutect2, varscan2
- TNXB | c.672C>G p.G224= | Silent (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- WDR17 | c.771T>C p.S257= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV54577267; called by muse, mutect2, varscan2
- ZMYND11 | c.558G>A p.P186= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs764007309; called by muse, mutect2, varscan2
- ZNF208 | c.1974T>C p.I658= | Silent (SNP) | VAF 45/52 reads (87%) | called by muse, varscan2
- ZNF329 | c.315C>T p.P105= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs765257889, COSV63771682; called by muse, mutect2, varscan2
- CISD1 | c.-2C>T | 5'UTR (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- NEDD8 | chr14:24213509 A>G | 3'Flank (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12770G>T | Intron (SNP) | VAF 22/54 reads (41%) | catalogued as COSV101042833, COSV67447323; called by mutect2, varscan2
